Somatic mutation profile of tumor specimen TCGA-50-6590-01A (aliquot TCGA-50-6590-01A-12D-1855-08) from TCGA case TCGA-50-6590, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 72.4 years (26,444 days).
Specimen TCGA-50-6590-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73691763-129a-4710-ae38-c26ce0eaa55c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-6590-11A (Solid Tissue Normal), aliquot TCGA-50-6590-11A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17a121d0-95bb-4caa-9472-436d9ea89f11

The open-access MAF lists 928 somatic variants for this specimen: 707 protein-altering or splice-affecting, 199 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 621, Silent 199, Nonsense Mutation 41, Frame Shift Del 18, Splice Site 15, RNA 9, Intron 7, Frame Shift Ins 5, Splice Region 4, 5'Flank 3, In Frame Del 2, Nonstop Mutation 1.

Variants (750 of 928; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHM | c.1019C>A p.S340* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | catalogued as rs1057517714, CM980358, COSV63301242; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.559+1G>T p.X187_splice | Splice Site (SNP) | VAF 17/47 reads (36%) | hotspot (GDC flag); catalogued as CS137624, COSV52670017, COSV52686439, COSV52695669; called by muse, mutect2, varscan2
- AADACL3 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 16/273 reads (6%) | catalogued as COSV60198674; called by muse, mutect2
- AASS | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV62789636; called by muse, mutect2, varscan2
- ABCA8 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV52198593; called by muse, mutect2, varscan2
- ABCC1 | c.1532G>T p.G511V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60683807; called by muse, mutect2, varscan2
- ABCC11 | c.3913A>T p.T1305S | Missense Mutation (SNP) | VAF 73/225 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62322555; called by muse, mutect2, varscan2
- ABCC11 | c.761A>G p.H254R | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV62322561; called by muse, mutect2, varscan2
- ABCC12 | c.2450G>T p.G817V | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as COSV60913143; called by muse, mutect2, varscan2
- ABCC8 | c.2420T>A p.L807Q | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56849016; called by muse, varscan2
- ABLIM3 | c.36C>A p.Y12* | Nonsense Mutation (SNP) | VAF 7/75 reads (9%) | catalogued as COSV58642085; called by muse, mutect2
- ABT1 | c.533C>G p.A178G | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51290995, COSV99223353; called by muse, mutect2
- ACCS | c.1370G>T p.R457L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55457826, COSV99772861; called by muse, mutect2, varscan2
- ACSM2B | c.1575G>T p.K525N | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as COSV61657458; called by muse, mutect2, varscan2
- ACTA1 | c.823G>T p.G275C | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64202808; called by muse, mutect2, varscan2
- ACVRL1 | c.134C>A p.T45N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.284); catalogued as COSV66359958; called by muse, mutect2, varscan2
- ADAM22 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as COSV55974293; called by muse, mutect2
- ADAMTS12 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61254538; called by muse, mutect2, varscan2
- ADAMTS17 | c.1227G>T p.R409S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as COSV51477613; called by muse, mutect2, varscan2
- ADD3 | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53321691; called by muse, mutect2
- ADGRB3 | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 27/294 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs373248973; called by muse, mutect2
- ADGRG2 | c.508G>T p.E170* (on ENST00000379869 / NM_001079858.3; = p.E167* on NM_005756.4) | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | catalogued as COSV61338519; called by muse, mutect2, varscan2
- ADGRG4 | c.7709G>T p.R2570L | Missense Mutation (SNP) | VAF 155/454 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV54953670, COSV54960507; called by muse, mutect2, varscan2
- ADGRL3 | c.3763G>C p.E1255Q (on ENST00000506720 / NM_001322402.2; = p.E1187Q on NM_015236.6) | Missense Mutation (SNP) | VAF 57/67 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV72230212, COSV72230468; called by muse, mutect2, varscan2
- ADGRL4 | c.1578G>T p.K526N | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV100875742; called by muse, mutect2
- ADNP2 | c.949G>T p.G317* | Nonsense Mutation (SNP) | VAF 19/79 reads (24%) | catalogued as COSV51537697; called by muse, mutect2, varscan2
- ADRA1A | c.1291C>A p.Q431K | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV52361762; called by muse, mutect2, varscan2
- AGPAT4 | c.112C>T p.L38F | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as rs780990230, COSV57244992; called by muse, mutect2, varscan2
- AK7 | c.1784G>A p.R595K | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV50870626; called by muse, varscan2
- AL592490.1 | c.1339G>T p.V447F | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.181); catalogued as COSV69425618; called by muse, mutect2, varscan2
- ALG3 | c.1168G>T p.G390W | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56611025; called by muse, mutect2, varscan2
- ALS2 | c.3808G>A p.E1270K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV51886105; called by muse, mutect2, varscan2
- ALS2CL | c.2299A>T p.S767C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV59671014; called by muse, mutect2, varscan2
- AMPH | c.2050G>C p.G684R | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57739429, COSV57740048, COSV57759654; called by muse, mutect2, varscan2
- ANGPT4 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | catalogued as COSV67921246, COSV67922814; called by muse, mutect2, varscan2
- ANKRD17 | c.6854C>T p.S2285L | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as COSV58218600; called by muse, mutect2, varscan2
- ANKRD44 | c.1840G>C p.E614Q | Missense Mutation (SNP) | VAF 19/201 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.34); catalogued as COSV56549849, COSV56553196; called by muse, mutect2
- ANO5 | c.245T>C p.F82S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV61083936; called by muse, mutect2, varscan2
- ANXA13 | c.799A>T p.T267S | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as COSV51622552; called by muse, mutect2, varscan2
- AOAH | c.706G>T p.V236F | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV51738872; called by muse, varscan2
- AP4M1 | c.37G>C p.D13H | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57995662; called by muse, mutect2
- APBA1 | c.1701C>A p.N567K | Missense Mutation (SNP) | VAF 18/291 reads (6%) | SIFT tolerated (0.92); PolyPhen benign (0.182); catalogued as COSV55225763; called by muse, mutect2
- APBB2 | c.1155A>T p.E385D (on ENST00000295974 / NM_001166050.2; = p.E386D on NM_004307.2) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as COSV55950799; called by muse, mutect2, varscan2
- APMAP | c.244C>G p.L82V | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV54173436; called by muse, mutect2
- ARID1B | c.2868G>C p.Q956H | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.964); catalogued as COSV51657874; called by muse, mutect2
- ASH1L | c.3260A>T p.Q1087L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); catalogued as COSV64207060; called by muse, mutect2, varscan2
- ATAD5 | c.5233C>G p.L1745V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58973573, COSV58979394; called by muse, mutect2, varscan2
- ATP1A4 | c.1757T>G p.M586R | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.356); catalogued as COSV63626128; called by muse, mutect2
- ATP1A4 | c.1759G>A p.D587N | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV63626132; called by muse, mutect2
- ATP6V0D2 | c.181C>G p.H61D | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV53414210; called by muse, mutect2, varscan2
- AUTS2 | c.646G>T p.G216* | Nonsense Mutation (SNP) | VAF 41/196 reads (21%) | catalogued as COSV61394682; called by muse, mutect2, varscan2
- B3GAT2 | c.679G>C p.V227L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs1328280287, COSV57770043; called by muse, mutect2, varscan2
- BAMBI | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65002855; called by muse, mutect2, varscan2
- BCAN | c.2617C>A p.P873T | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV61256400; called by muse, mutect2, varscan2
- BCAS3 | c.1903G>A p.A635T (on ENST00000390652 / NM_001353144.2; = p.A620T on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.113); catalogued as COSV66772344; called by muse, mutect2, varscan2
- BCHE | c.320C>A p.S107* | Nonsense Mutation (SNP) | VAF 28/70 reads (40%) | catalogued as COSV52255625; called by muse, mutect2, varscan2
- BICD1 | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV55677675; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3445G>T p.A1149S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV63244763; called by muse, mutect2, varscan2
- BPNT1 | c.365C>A p.T122N | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59039576; called by muse, mutect2
- BRD4 | c.2593G>A p.A865T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.361); catalogued as rs1291730650, COSV54584963; called by muse, mutect2
- BSN | c.8606C>A p.S2869Y | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV56515979; called by muse, mutect2, varscan2
- C10orf90 | c.1882C>A p.P628T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52953166; called by muse, mutect2, varscan2
- C11orf42 | c.713C>G p.P238R | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.16); catalogued as COSV56410779; called by muse, mutect2, varscan2
- C22orf42 | c.651G>T p.E217D | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.388); catalogued as COSV66075683; called by muse, mutect2
- C2orf16 | c.5800C>T p.R1934C | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.57); catalogued as rs1184118126, COSV62674940; called by muse, mutect2
- C5 | c.1735G>C p.A579P | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.105); catalogued as COSV56326221; called by muse, mutect2, varscan2
- C6orf118 | c.736G>C p.E246Q | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs1400884378, COSV57814230; called by muse, mutect2, varscan2
- CABCOCO1 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57592573; called by muse, mutect2
- CACNA1C | c.686C>A p.A229D | Missense Mutation (SNP) | VAF 103/249 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59709713; called by muse, mutect2, varscan2
- CACNA1D | c.2128G>T p.V710L (on ENST00000350061 / NM_001128840.3; = p.V730L on NM_000720.4) | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs1465997147, COSV55443757; called by muse, varscan2
- CACNA1E | c.3583G>A p.G1195S | Missense Mutation (SNP) | VAF 30/398 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV62389888; called by muse, mutect2
- CACNA1E | c.4034G>T p.G1345V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV62389899; called by muse, mutect2, varscan2
- CACNA1E | c.4269C>G p.I1423M | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62389913; called by muse, mutect2
- CALD1 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.27); catalogued as COSV62646958; called by muse, mutect2, varscan2
- CALHM2 | c.314C>G p.S105C | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV53295258; called by muse, mutect2, varscan2
- CAND1 | c.1801G>T p.G601* | Nonsense Mutation (SNP) | VAF 37/157 reads (24%) | catalogued as COSV73389580; called by muse, mutect2, varscan2
- CAPN11 | c.1864A>C p.M622L | Missense Mutation (SNP) | VAF 83/262 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs757579344, COSV67237107; called by muse, mutect2, varscan2
- CASP5 | c.610G>C p.D204H | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV52827943; called by muse, mutect2, varscan2
- CASR | c.883G>T p.A295S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as COSV56136481; called by muse, mutect2, varscan2
- CCDC171 | c.926G>T p.R309L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV52639464; called by muse, mutect2, varscan2
- CCDC28A | c.414G>T p.E138D | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.416); catalogued as COSV60424804; called by muse, mutect2
- CCDC85A | c.729G>T p.E243D | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.708); catalogued as COSV68149670; called by muse, mutect2, varscan2
- CCS | c.388C>A p.H130N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.1); catalogued as COSV59578764; called by muse, mutect2, varscan2
- CD163 | c.1369T>C p.W457R | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63131426; called by muse, mutect2, varscan2
- CD300A | c.112T>A p.Y38N | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60409853; called by muse, mutect2, varscan2
- CDH1 | c.387G>T p.Q129H | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs764700595, COSV55730853; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDH11 | c.2383G>T p.D795Y | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as rs1471732983, COSV51758237, COSV51771976; called by muse, mutect2, varscan2
- CDH2 | c.2293G>A p.D765N | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52277453; called by muse, mutect2, varscan2
- CDH4 | c.813T>A p.N271K | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as COSV64649854; called by muse, mutect2, varscan2
- CDH8 | c.1476C>A p.N492K | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV54860501, COSV54863209; called by muse, mutect2, varscan2
- CDK18 | c.106del p.Q36Sfs*57 (on ENST00000506784 / NM_212503.3; = p.Q36Sfs*110 on NM_002596.4) | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | catalogued as rs1443976120; called by mutect2, pindel, varscan2
- CENPT | c.1674C>A p.F558L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV54649030; called by muse, mutect2, varscan2
- CEP170 | c.3896G>A p.R1299Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.986); catalogued as COSV60508136; called by muse, mutect2, varscan2
- CFAP47 | c.773G>C p.G258A | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99934646; called by muse, mutect2, varscan2
- CFAP52 | c.1192A>C p.I398L | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.42); catalogued as COSV55344286; called by muse, mutect2, varscan2
- CFAP58 | c.2479C>A p.L827I | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV63833675; called by muse, mutect2, varscan2
- CHD6 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100497945, COSV58556008; called by muse, mutect2
- CHGB | c.146G>T p.S49I | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs1204804176, COSV66760128; called by muse, mutect2
- CHRM3 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV55086548; called by muse, mutect2, varscan2
- CHSY3 | c.2047A>G p.K683E | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV100518743; called by mutect2, varscan2
- CIP2A | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs756073947, COSV55418241; called by muse, mutect2, varscan2
- CKAP2L | c.1513G>C p.E505Q | Missense Mutation (SNP) | VAF 65/235 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV56696163; called by muse, mutect2, varscan2
- CLVS2 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV51560893; called by muse, mutect2, varscan2
- CNOT10 | c.117+1G>T p.X39_splice | Splice Site (SNP) | VAF 14/74 reads (19%) | catalogued as COSV59391483; called by muse, mutect2
- CNTN1 | c.2255A>T p.E752V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV61638612; called by muse, mutect2, varscan2
- CNTN3 | c.2828G>T p.R943M | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99723769; called by muse, mutect2, varscan2
- CNTN3 | c.2827A>T p.R943W | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as COSV99723773; called by muse, mutect2, varscan2
- COL11A1 | c.3196G>A p.G1066S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62180037; called by muse, mutect2, varscan2
- COL14A1 | c.1498G>T p.E500* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV52851916; called by muse, mutect2, varscan2
- COL14A1 | c.4613C>T p.P1538L | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV52851926, COSV52852381; called by muse, mutect2
- COL20A1 | c.2768C>A p.A923D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58915045; called by mutect2, varscan2
- COL22A1 | c.1540G>A p.G514R | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57332302, COSV57349347; called by muse, varscan2
- COL5A2 | c.949C>A p.P317T | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV66408763; called by muse, mutect2, varscan2
- COL6A6 | c.2450C>A p.S817Y | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62022538; called by muse, mutect2, varscan2
- COL6A6 | c.4183G>T p.G1395C | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62022554; called by muse, mutect2, varscan2
- COP1 | c.2054G>A p.S685N | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.878); catalogued as COSV58165654; called by muse, mutect2, varscan2
- CPB2 | c.384+1G>A p.X128_splice | Splice Site (SNP) | VAF 22/116 reads (19%) | catalogued as COSV51673485; called by muse, mutect2, varscan2
- CPSF7 | c.550G>T p.G184* (on ENST00000394888 / NM_001136040.4; = p.G227* on NM_024811.4) | Nonsense Mutation (SNP) | VAF 27/124 reads (22%) | catalogued as COSV61210779; called by muse, mutect2, varscan2
- CR2 | c.331G>T p.G111C | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65507133; called by muse, mutect2, varscan2
- CRISP2 | c.494A>G p.Y165C | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59254151, COSV59257078; called by muse, mutect2, varscan2
- CRTAM | c.145C>A p.Q49K | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57067802; called by muse, mutect2, varscan2
- CSMD3 | c.4594G>T p.G1532W (on ENST00000297405 / NM_001363185.1; = p.G1428W on NM_052900.3) | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52152602; called by muse, mutect2, varscan2
- CSMD3 | c.4298T>A p.F1433Y (on ENST00000297405 / NM_001363185.1; = p.F1329Y on NM_052900.3) | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.977); catalogued as COSV52152619; called by muse, mutect2, varscan2
- CSMD3 | c.2863C>A p.P955T (on ENST00000297405 / NM_001363185.1; = p.P851T on NM_052900.3) | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV52152640; called by muse, mutect2, varscan2
- CSMD3 | c.2347C>A p.P783T (on ENST00000297405 / NM_001363185.1; = p.P679T on NM_052900.3) | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.065); catalogued as COSV52152658; called by muse, mutect2, varscan2
- CSMD3 | c.1591G>A p.E531K (on ENST00000297405 / NM_001363185.1; = p.E427K on NM_052900.3) | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV52152676; called by muse, mutect2, varscan2
- CTNNA2 | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.511); catalogued as rs760574291, COSV63559645, COSV63597945; called by muse, mutect2, varscan2
- CTNNBL1 | c.1371G>C p.K457N | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100799399; called by muse, mutect2, varscan2
- CTSK | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV55011436; called by muse, mutect2
- CTTNBP2 | c.2243T>A p.L748* | Nonsense Mutation (SNP) | VAF 34/246 reads (14%) | catalogued as COSV50395473; called by muse, mutect2, varscan2
- CWH43 | c.1766G>T p.R589I | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56937948; called by muse, mutect2, varscan2
- CXCL9 | c.366G>C p.K122N | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV53578684; called by muse, mutect2, varscan2
- CXXC5 | c.53G>T p.S18I | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV56795012; called by muse, mutect2
- CYP11B1 | c.1261G>C p.E421Q | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52826182, COSV99455789; called by muse, mutect2, varscan2
- CYP26B1 | c.355C>G p.R119G | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV50010610, COSV50011475; called by muse, mutect2, varscan2
- CYRIA | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.25); catalogued as COSV62864769; called by muse, mutect2, varscan2
- DCAF12L1 | c.1339G>T p.G447W | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64421562; called by muse, mutect2, varscan2
- DCAF8L1 | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.046); catalogued as rs1277200484, COSV71595218; called by muse, mutect2, varscan2
- DCC | c.1939C>T p.P647S | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.56); catalogued as COSV59097158; called by muse, mutect2, varscan2
- DDX60L | c.1210G>T p.V404F | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV52711812; called by muse, mutect2, varscan2
- DENND2A | c.1053C>A p.D351E | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.573); catalogued as COSV52050076; called by muse, mutect2, varscan2
- DGCR6L | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.973); catalogued as COSV50618952; called by muse, mutect2
- DGKB | c.32G>C p.S11T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV51775278; called by muse, mutect2, varscan2
- DHX57 | c.1295A>G p.Y432C | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs534676110, COSV54884157; called by muse, mutect2
- DHX9 | c.1396G>C p.G466R | Missense Mutation (SNP) | VAF 15/219 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62358991; called by muse, mutect2
- DLGAP3 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV52398681; called by muse, mutect2
- DMXL1 | c.4153G>T p.D1385Y | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs752034248, COSV60709085; called by muse, mutect2, varscan2
- DNAH10 | c.1684C>A p.R562S (on ENST00000409039; = p.R501S on NM_207437.3) | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.525); catalogued as COSV68991562; called by muse, mutect2, varscan2
- DNAH11 | c.1853A>T p.E618V | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV60951421; called by muse, mutect2, varscan2
- DNAH17 | c.7795G>T p.A2599S | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.662); catalogued as COSV101101734; called by muse, mutect2, varscan2
- DNAH9 | c.3220A>T p.R1074W | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV52344811; called by muse, mutect2, varscan2
- DNAH9 | c.4622A>T p.K1541I | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV52344818; called by muse, mutect2, varscan2
- DOCK10 | c.3957G>C p.L1319F | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as COSV51373033; called by muse, mutect2, varscan2
- DOCK10 | c.1370G>T p.G457V | Missense Mutation (SNP) | VAF 34/215 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.393); catalogued as COSV51373283; called by muse, mutect2, varscan2
- DPH2 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.225); catalogued as COSV99356311; called by muse, mutect2, varscan2
- DSC3 | c.1813G>T p.G605* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV64571714, COSV64572586; called by muse, mutect2, varscan2
- DSG3 | c.693C>A p.S231R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57125485; called by muse, mutect2, varscan2
- DSTYK | c.2768G>A p.R923K | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV100904499; called by muse, mutect2, varscan2
- DTNB | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56472198, COSV56475237; called by muse, mutect2, varscan2
- DUXA | c.458G>T p.R153I | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV73729595, COSV73729744; called by muse, mutect2, varscan2
- DVL3 | c.1730G>T p.G577V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53047707, COSV99491063; called by muse, mutect2, varscan2
- ECT2L | c.773T>C p.I258T | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV62883928; called by muse, mutect2
- EED | c.955A>C p.I319L | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV54554730; called by muse, mutect2
- EEF1A2 | c.934G>T p.V312L | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as COSV53205664; called by muse, mutect2, varscan2
- EEF2K | c.932C>G p.S311C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53780645, COSV53786294; called by muse, mutect2, varscan2
- EFCAB5 | c.3754G>A p.V1252I | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as COSV57928279; called by muse, mutect2, varscan2
- EFNA2 | c.336G>T p.W112C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53065321; called by muse, mutect2, varscan2
- EFTUD2 | c.719A>T p.E240V | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV68182785; called by muse, mutect2
- EIF3B | c.1290-1G>A p.X430_splice | Splice Site (SNP) | VAF 37/161 reads (23%) | catalogued as COSV62803182; called by muse, mutect2, varscan2
- ELMOD1 | c.182C>G p.S61C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56192008; called by muse, mutect2, varscan2
- EMX1 | c.776C>A p.S259Y | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99252427; called by muse, mutect2, varscan2
- ENO3 | c.775C>G p.L259V | Missense Mutation (SNP) | VAF 62/339 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV52776961; called by muse, mutect2, varscan2
- ENPP5 | c.384G>C p.Q128H | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100040378; called by muse, mutect2, varscan2
- EPHB6 | c.98A>T p.E33V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67418116; called by muse, mutect2, varscan2
- EPHB6 | c.1412G>T p.S471I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs772331271, COSV100844405, COSV63891302; called by muse, mutect2, varscan2
- ERICH3 | c.1424T>A p.M475K | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV58604238; called by muse, mutect2
- ERICH3 | c.1257G>T p.E419D | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.554); catalogued as COSV58604258; called by muse, mutect2, varscan2
- ERO1A | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV101193584; called by muse, mutect2, varscan2
- EXD1 | c.523C>A p.L175M | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs765118229, COSV59253514; called by mutect2, varscan2
- EXOC7 | c.1960G>C p.E654Q (on ENST00000335146 / NM_001145297.4; = p.E572Q on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV58035720; called by muse, mutect2
- EYA1 | c.655C>A p.P219T | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV58160572; called by muse, mutect2
- F13B | c.286C>A p.L96M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66373311; called by muse, mutect2, varscan2
- FAM171B | c.1696G>A p.G566R | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV59002495; called by muse, mutect2, varscan2
- FAM20B | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55379855; called by muse, mutect2, varscan2
- FAM98C | c.962A>T p.E321V | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53038594; called by muse, mutect2, varscan2
- FANCC | c.1089C>A p.H363Q | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV56659428; called by muse, mutect2, varscan2
- FANK1 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1220262753, COSV64158188; called by muse, mutect2, varscan2
- FAP | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.221); catalogued as rs368690170; called by mutect2, varscan2
- FAT3 | c.8919T>G p.F2973L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53098253; called by muse, mutect2, varscan2
- FAT4 | c.12734T>A p.V4245E | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); catalogued as COSV58679631; called by muse, mutect2, varscan2
- FECH | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV50490639; called by muse, mutect2, varscan2
- FGF12 | c.265C>A p.P89T (on ENST00000454309 / NM_021032.5; = p.P27T on NM_004113.6) | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV53160381; called by muse, mutect2, varscan2
- FHL5 | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58736915; called by muse, mutect2
- FHOD3 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.976); catalogued as rs374440269; called by mutect2, varscan2
- FILIP1L | c.2366_2368del p.R789del (on ENST00000354552 / NM_182909.3; = p.R549del on NM_014890.3 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 60/169 reads (36%) | catalogued as rs1396473736; called by pindel, varscan2
- FLG | c.9788G>A p.G3263D | Missense Mutation (SNP) | VAF 50/602 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV64240200; called by muse, mutect2
- FMN2 | c.2972C>T p.P991L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as rs758399423, COSV60426482; called by muse, varscan2
- FOCAD | c.532C>G p.L178V | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV58097013, COSV58101670; called by muse, mutect2, varscan2
- FOXRED1 | c.188A>T p.H63L | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.288); catalogued as COSV55006053; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.01); catalogued as rs749528030, COSV100598574, COSV63049029; called by mutect2, varscan2
- FRAS1 | c.3283A>G p.T1095A | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV53603407; called by muse, mutect2, varscan2
- FRMPD4 | c.1395C>A p.S465R | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV66213588; called by muse, mutect2, varscan2
- FSHR | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV58621585; called by muse, mutect2
- GABRB3 | c.704T>A p.L235Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54659315; called by muse, mutect2, varscan2
- GAK | c.2852G>C p.R951T | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV58503962; called by muse, mutect2, varscan2
- GAL3ST3 | c.738G>T p.E246D | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61748807; called by muse, mutect2, varscan2
- GARRE1 | c.426G>T p.M142I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); catalogued as COSV55098355; called by muse, mutect2, varscan2
- GCN1 | c.3685G>C p.D1229H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56106445; called by muse, mutect2, varscan2
- GEM | c.656A>G p.E219G | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99891200; called by muse, mutect2, varscan2
- GEM | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753149152, COSV99891208; called by muse, mutect2, varscan2
- GFRAL | c.413G>T p.C138F | Missense Mutation (SNP) | VAF 83/309 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61229856, COSV61230195; called by muse, mutect2, varscan2
- GJC1 | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV57910999; called by muse, mutect2
- GLI1 | c.2947C>T p.H983Y | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.09); catalogued as COSV57360619; called by muse, mutect2, varscan2
- GLRA1 | c.847C>A p.L283I | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV51010336; called by muse, mutect2, varscan2
- GLTP | c.606C>A p.N202K | Missense Mutation (SNP) | VAF 87/290 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs891473014, COSV59172699, COSV59173283; called by muse, mutect2, varscan2
- GNAS | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); catalogued as COSV58332462; called by muse, mutect2, varscan2
- GOLGA6B | c.1078C>A p.L360M | Missense Mutation (SNP) | VAF 47/313 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.635); catalogued as COSV69770062; called by muse, mutect2, varscan2
- GOLT1B | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57553312; called by muse, mutect2, varscan2
- GON4L | c.5366A>G p.E1789G | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55191508; called by muse, mutect2, varscan2
- GPATCH8 | c.3857G>T p.S1286I | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.22); catalogued as COSV59194195; called by muse, mutect2, varscan2
- GPKOW | c.525G>T p.M175I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV50242421, COSV50243674; called by muse, mutect2, varscan2
- GPR158 | c.1563G>T p.M521I | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV66268371; called by muse, mutect2, varscan2
- GPR65 | c.377G>T p.R126M | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99965974; called by muse, mutect2, varscan2
- GPR65 | c.378G>T p.R126S | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV99965976; called by muse, mutect2, varscan2
- GPRASP1 | c.2079G>T p.W693C | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.737); catalogued as COSV64355345; called by muse, mutect2, varscan2
- GRIA1 | c.1195G>T p.G399C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV53598454, COSV53614671; called by muse, mutect2, varscan2
- GRIA3 | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV52055748; called by mutect2, varscan2
- GRIN1 | c.462G>T p.M154I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.051); catalogued as COSV59294446; called by muse, mutect2, varscan2
- GRIN2A | c.2902G>C p.A968P | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as CM1111633, COSV58028681; called by muse, mutect2
- GRM1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51128372; called by muse, mutect2, varscan2
- GTF2H3 | c.875C>G p.S292C | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.753); catalogued as COSV57458542; called by muse, mutect2, varscan2
- GUCY1A2 | c.1462A>T p.K488* | Nonsense Mutation (SNP) | VAF 9/84 reads (11%) | catalogued as COSV56483853; called by muse, mutect2, varscan2
- GUCY1A2 | c.571G>T p.A191S | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV99973624; called by muse, mutect2, varscan2
- H2BC21 | c.285C>G p.I95M | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV58611804; called by muse, mutect2
- HCRTR2 | c.403-2A>G p.X135_splice | Splice Site (SNP) | VAF 15/48 reads (31%) | catalogued as COSV63795116; called by muse, varscan2
- HEPH | c.2544G>T p.W848C (on ENST00000343002; = p.W581C on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.088); catalogued as COSV57961850; called by muse, mutect2, varscan2
- HFM1 | c.367T>C p.Y123H | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.467); catalogued as COSV54025578; called by muse, mutect2, varscan2
- HHIPL2 | c.338C>A p.A113E | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100596617, COSV58564516; called by muse, mutect2, varscan2
- HIVEP3 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56013494; called by muse, mutect2, varscan2
- HMCN1 | c.1877G>T p.G626V | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54892367; called by muse, mutect2, varscan2
- HRG | c.772C>T p.H258Y | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.169); catalogued as rs1458447850, COSV51644892; called by muse, mutect2, varscan2
- IDE | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV56422627; called by muse, mutect2, varscan2
- IGHD | c.223C>A p.Q75K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as COSV101162817; called by muse, mutect2, varscan2
- IGSF8 | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as rs757751259, COSV58757781; called by mutect2, varscan2
- IKZF1 | c.779G>T p.R260I | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV58780825, COSV58792834; called by muse, mutect2, varscan2
- IL18R1 | c.898G>C p.V300L | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.84); PolyPhen benign (0.017); catalogued as COSV52123935; called by muse, mutect2, varscan2
- IL5RA | c.88C>A p.L30I | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as COSV56522639; called by muse, mutect2
- ING1 | c.127G>T p.G43W | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV100312016; called by muse, mutect2, varscan2
- ING1 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.154); catalogued as COSV58171807; called by muse, mutect2, varscan2
- INMT | c.55G>T p.D19Y | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV50000940; called by muse, mutect2, varscan2
- INPP4B | c.1332G>C p.K444N | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.208); catalogued as COSV53720075, COSV53743044; called by muse, mutect2, varscan2
- INTS1 | c.904G>C p.A302P | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); catalogued as COSV67177126; called by muse, mutect2, varscan2
- IPMK | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.089); catalogued as COSV64243603; called by muse, mutect2
- IRAK2 | c.731G>T p.C244F | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.181); catalogued as COSV56530653; called by muse, mutect2, varscan2
- IRS1 | c.1742C>A p.S581Y | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV59335358; called by muse, mutect2, varscan2
- ITGAM | c.3132C>G p.F1044L (on ENST00000648685 / NM_001145808.2; = p.F1043L on NM_000632.4) | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs756051605, COSV54936105; called by muse, mutect2, varscan2
- ITGB8 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV56006968; called by muse, mutect2, varscan2
- ITIH1 | c.1929C>G p.F643L | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV56254064; called by muse, mutect2, varscan2
- ITIH5 | c.1850C>A p.P617H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99904096; called by muse, mutect2, varscan2
- ITIH6 | c.3070C>T p.P1024S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.092); catalogued as COSV54488222; called by muse, mutect2, varscan2
- IZUMO4 | c.609-2A>C p.X203_splice (on ENST00000395301 / NM_001039846.2; = p.X185_splice on NM_001031735.3) | Splice Site (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100642483; called by muse, mutect2, varscan2
- JARID2 | c.2178G>T p.E726D | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.817); catalogued as COSV59188059; called by muse, mutect2
- JMJD1C | c.3592C>A p.R1198S | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV59514095; called by muse, mutect2, varscan2
- KANSL1 | c.2261T>G p.V754G | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.23); catalogued as COSV99294246; called by muse, mutect2, varscan2
- KANSL1 | c.2260G>T p.V754L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV52267791; called by muse, mutect2, varscan2
- KCNA3 | c.1363A>T p.I455L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.129); catalogued as COSV100871223; called by muse, varscan2
- KCNG4 | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1324319297, COSV100376953; called by muse, mutect2, varscan2
- KCNMB1 | c.314A>T p.Y105F | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV51131679; called by muse, mutect2
- KCNN2 | c.976G>C p.A326P (on ENST00000264773; = p.A538P on NM_021614.4) | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as COSV53295207, COSV99299133; called by muse, mutect2, varscan2
- KCTD3 | c.137G>T p.S46I | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV52065937; called by muse, mutect2
- KCTD8 | c.1254C>A p.S418R | Missense Mutation (SNP) | VAF 81/379 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV63587858; called by muse, mutect2, varscan2
- KDELR3 | c.48G>C p.M16I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53247282, COSV53247606; called by muse, mutect2, varscan2
- KDELR3 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 40/386 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as rs752256020, COSV53247310; called by muse, mutect2, varscan2
- KDM6B | c.410G>C p.G137A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.028); catalogued as COSV54680231; called by muse, mutect2, varscan2
- KDM7A | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.639); catalogued as COSV50090826; called by muse, mutect2, varscan2
- KDR | c.1062C>A p.Y354* | Nonsense Mutation (SNP) | VAF 124/239 reads (52%) | catalogued as COSV55762430; called by muse, mutect2, varscan2
- KHNYN | c.733T>A p.C245S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99249535; called by muse, mutect2, varscan2
- KIAA1549L | c.580C>A p.P194T (on ENST00000321505; = p.P491T on NM_012194.3) | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); catalogued as COSV55772057; called by muse, mutect2, varscan2
- KIF20B | c.2761C>G p.L921V (on ENST00000371728 / NM_001284259.2; = p.L881V on NM_016195.4) | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as COSV53305491; called by muse, mutect2, varscan2
- KIF3C | c.260A>T p.Q87L | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.104); catalogued as COSV53098812; called by muse, mutect2
- KIF7 | c.1682C>A p.P561H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV101067366; called by muse, mutect2, varscan2
- KIF7 | c.1681C>A p.P561T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.261); catalogued as rs1325092086, COSV101067367; called by muse, mutect2, varscan2
- KIR3DL1 | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 111/396 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV58489777; called by muse, mutect2, varscan2
- KLHL15 | c.1534A>G p.T512A | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); catalogued as COSV60139939; called by muse, mutect2, varscan2
- KLHL41 | c.759A>T p.K253N | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs1559129514, COSV52929858; called by muse, mutect2
- KLHL42 | c.508G>T p.G170W | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as COSV67145797; called by muse, mutect2, varscan2
- KLHL7 | c.45G>C p.E15D | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated, low confidence (0.43); PolyPhen possibly damaging (0.636); catalogued as COSV59160894; called by muse, mutect2, varscan2
- KNDC1 | c.4607A>T p.Q1536L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV58835014; called by muse, mutect2
- KNTC1 | c.5869G>A p.E1957K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); catalogued as rs759532010, COSV61079466; called by muse, varscan2
- KRT24 | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV52880074; called by muse, mutect2
- KRT32 | c.56C>A p.P19H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.27); catalogued as COSV56786316; called by muse, mutect2, varscan2
- KRTAP13-2 | c.371C>A p.S124Y | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV101299627; called by muse, mutect2, varscan2
- LAMA1 | c.7735A>T p.S2579C | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV67535184; called by muse, mutect2, varscan2
- LAMB3 | c.2509G>A p.E837K | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV61916334; called by muse, mutect2, varscan2
- LAMB4 | c.35-1G>T p.X12_splice | Splice Site (SNP) | VAF 23/108 reads (21%) | catalogued as COSV52717267; called by muse, mutect2, varscan2
- LAMC3 | c.2842G>T p.D948Y | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63090170; called by muse, mutect2, varscan2
- LARP1 | c.1001G>T p.R334L (on ENST00000518297 / NM_033551.3; = p.R257L on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.297); catalogued as COSV100303303, COSV60426153; called by muse, mutect2, varscan2
- LATS1 | c.2285A>G p.N762S | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.627); catalogued as COSV53586142, COSV53589377; called by muse, mutect2, varscan2
- LDB2 | c.640C>A p.Q214K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV58766599, COSV58784337; called by muse, mutect2, varscan2
- LGALS4 | c.564C>G p.F188L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV57043436; called by muse, mutect2, varscan2
- LHPP | c.671A>T p.Q224L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV64328876; called by muse, mutect2, varscan2
- LILRB5 | c.1489C>A p.P497T (on ENST00000449561 / NM_001081442.3; = p.P496T on NM_006840.5) | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs767274971, COSV60256514, COSV60260126; called by muse, mutect2, varscan2
- LONP1 | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.022); catalogued as rs538226936, COSV100638559; called by muse, mutect2, varscan2
- LONP1 | c.753C>G p.S251R | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.127); catalogued as rs762359188, COSV100638560, COSV62262193; called by muse, mutect2, varscan2
- LPP | c.1411-1G>C p.X471_splice | Splice Site (SNP) | VAF 8/87 reads (9%) | catalogued as COSV57086414; called by muse, mutect2
- LRCH1 | c.1785G>C p.K595N | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV60846129; called by muse, mutect2, varscan2
- LRIF1 | c.1831G>C p.E611Q | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.221); catalogued as COSV63897101; called by muse, mutect2
- LRP1B | c.7289G>C p.R2430P | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67206126, COSV67212753; called by muse, mutect2, varscan2
- LRRC41 | c.2077G>C p.E693Q | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as COSV58439635; called by muse, mutect2
- LRRC4C | c.29A>T p.Q10L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV53421323; called by muse, mutect2, varscan2
- LRRIQ1 | c.5005G>T p.V1669F | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67829070; called by muse, mutect2, varscan2
- LRRIQ3 | c.20C>A p.T7K | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV63042854; called by muse, mutect2
- LYST | c.8036C>T p.S2679L | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as COSV67705971; called by muse, mutect2, varscan2
- MACC1 | c.1104A>C p.K368N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV60541984; called by muse, mutect2, varscan2
- MACF1 | c.10618G>A p.E3540K | Missense Mutation (SNP) | VAF 8/71 reads (11%) | catalogued as COSV57116899; called by muse, mutect2, varscan2
- MAGEL2 | c.3075T>A p.N1025K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV58566607; called by muse, mutect2, varscan2
- MAGI2 | c.2964C>A p.H988Q | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62643489; called by muse, mutect2, varscan2
- MAN2A1 | c.505T>C p.F169L | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV54850382; called by muse, mutect2, varscan2
- MAN2A1 | c.668G>T p.W223L | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54850390; called by muse, mutect2, varscan2
- MAP3K20 | c.2347G>T p.A783S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.027); catalogued as COSV64377923, COSV64379461; called by muse, mutect2
- MAPK8IP3 | c.3478G>C p.G1160R | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51599842, COSV51600283; called by muse, mutect2
- MARK2 | c.430C>A p.H144N | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV59282326; called by muse, mutect2, varscan2
- MAST2 | c.4195T>A p.S1399T | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100787955; called by muse, mutect2, varscan2
- MC3R | c.288C>G p.I96M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.798); catalogued as COSV54763522; called by muse, mutect2, varscan2
- MDC1 | c.4756C>T p.Q1586* | Nonsense Mutation (SNP) | VAF 121/393 reads (31%) | catalogued as COSV64524159; called by muse, mutect2, varscan2
- MDGA1 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.94); PolyPhen benign (0.115); catalogued as rs372332601; called by muse, mutect2
- MDGA2 | c.1724C>A p.S575Y (on ENST00000399232 / NM_001113498.2; = p.S277Y on NM_182830.4) | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62086738; called by muse, mutect2, varscan2
- MED16 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV54125299; called by muse, mutect2, varscan2
- MED17 | c.1592A>T p.Q531L | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV52600635; called by muse, mutect2, varscan2
- MEP1A | c.1316G>T p.R439L | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV57919378, COSV57921600; called by muse, mutect2, varscan2
- MFSD11 | c.842C>G p.S281C | Missense Mutation (SNP) | VAF 9/206 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.063); catalogued as COSV60622657; called by muse, mutect2
- MGAM | c.3059C>T p.S1020F | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV72074432, COSV72075227; called by muse, mutect2, varscan2
- MICALL2 | c.2552G>T p.R851L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748412801, COSV52515260; called by muse, mutect2, varscan2
- MID2 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV53308573, COSV53313086; called by muse, mutect2, varscan2
- MLIP | c.1311C>A p.C437* | Nonsense Mutation (SNP) | VAF 31/106 reads (29%) | catalogued as COSV51428535; called by muse, mutect2, varscan2
- MMP1 | c.757A>T p.I253F | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59510119; called by muse, mutect2, varscan2
- MMP27 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52780456; called by muse, mutect2, varscan2
- MMRN1 | c.1616G>C p.S539T | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV53336234, COSV53340512; called by muse, mutect2, varscan2
- MMRN1 | c.2413A>C p.T805P | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV99306772; called by muse, mutect2, varscan2
- MNDA | c.1005G>T p.K335N | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs372443942, COSV63741572; called by muse, mutect2, varscan2
- MROH2B | c.691C>A p.L231M | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.192); catalogued as COSV68182893; called by muse, mutect2, varscan2
- MROH5 | c.404C>A p.P135Q | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.16); catalogued as COSV71301063; called by muse, mutect2, varscan2
- MROH9 | c.407C>A p.S136* | Nonsense Mutation (SNP) | VAF 41/136 reads (30%) | catalogued as COSV63010837; called by muse, mutect2, varscan2
- MROH9 | c.1373G>A p.C458Y | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63010840; called by muse, mutect2
- MSN | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.257); catalogued as COSV64303723; called by muse, mutect2
- MSTN | c.5A>T p.Q2L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.051); catalogued as COSV99640588; called by muse, mutect2
- MTG1 | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs762012935, COSV58153417; called by muse, mutect2, varscan2
- MTOR | c.2513A>T p.Q838L | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV63870098; called by muse, mutect2, varscan2
- MUC6 | c.1133C>A p.T378N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.83); catalogued as COSV70139415; called by muse, mutect2, varscan2
- MYH7B | c.1972C>A p.Q658K | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.205); catalogued as rs372648708; called by muse, mutect2, varscan2
- MYO16 | c.3476G>A p.R1159K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as rs567225624, COSV62748764; called by muse, mutect2, varscan2
- MYO18B | c.4738C>A p.H1580N | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1412980415, COSV59131169; called by muse, mutect2, varscan2
- MYO18B | c.7487C>T p.P2496L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs367581364; called by muse, mutect2, varscan2
- MYO1A | c.2824G>T p.G942W | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV55653227; called by muse, mutect2, varscan2
- MYO1D | c.335G>T p.S112I | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59010825; called by muse, mutect2, varscan2
- MYO3B | c.3371G>T p.G1124V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV58700667; called by muse, mutect2
- NEFH | c.2197C>A p.P733T | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as COSV60216408; called by muse, varscan2
- NELL2 | c.1370G>T p.C457F | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61572766; called by muse, mutect2, varscan2
- NEU4 | c.104C>G p.T35S (on ENST00000391969 / NM_001167602.3; = p.T47S on NM_080741.4) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.733); catalogued as COSV57990088; called by muse, mutect2
- NFATC3 | c.2995G>A p.D999N | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.989); catalogued as COSV60472848; called by muse, mutect2
- NFKBID | c.523C>T p.P175S (on ENST00000396901; = p.P327S on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV61728273; called by muse, mutect2, varscan2
- NIM1K | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV58139000, COSV58140964; called by muse, mutect2, varscan2
- NLRP2 | c.1779G>T p.K593N | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.91); PolyPhen benign (0.306); catalogued as rs1247177445, COSV54754005; called by muse, mutect2, varscan2
- NLRP3 | c.1169C>A p.A390D | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV60222642; called by muse, mutect2, varscan2
- NLRP5 | c.1330C>A p.R444S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.063); catalogued as COSV66762103, COSV66763686; called by muse, mutect2, varscan2
- NLRP7 | c.2083C>G p.L695V (on ENST00000340844 / NM_206828.3; = p.L667V on NM_139176.3) | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV60173026; called by muse, mutect2
- NOTCH2 | c.414A>T p.T138= | Splice Region (SNP) | VAF 26/145 reads (18%) | catalogued as COSV56688480; called by muse, mutect2, varscan2
- NOTCH3 | c.1220G>T p.R407M | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs770646950, COSV54632059; called by muse, mutect2, varscan2
- NOVA1 | c.430C>G p.P144A | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.981); catalogued as COSV57475079; called by muse, mutect2, varscan2
- NPBWR1 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100488140, COSV58696846; called by muse, mutect2, varscan2
- NPHP4 | c.569A>T p.K190M | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV65394379; called by muse, mutect2, varscan2
- NR4A2 | c.1240A>G p.M414V | Missense Mutation (SNP) | VAF 13/197 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.091); catalogued as COSV59893378; called by muse, mutect2
- NRXN1 | c.3445G>T p.A1149S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.049); catalogued as COSV58446057, COSV58497815; called by muse, mutect2, varscan2
- NTSR1 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV65138379; called by muse, mutect2, varscan2
- NUDCD1 | c.1520A>T p.Y507F | Missense Mutation (SNP) | VAF 86/334 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.088); catalogued as COSV53456064; called by muse, mutect2, varscan2
- NUDCD1 | c.1350A>T p.K450N | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.072); catalogued as COSV53456090; called by muse, mutect2, varscan2
- OGT | c.2088G>C p.L696F | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.485); catalogued as COSV101035261; called by muse, mutect2
- OPHN1 | c.1194G>T p.E398D | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV62781631; called by muse, mutect2, varscan2
- OPN5 | c.903C>A p.Y301* | Nonsense Mutation (SNP) | VAF 46/170 reads (27%) | catalogued as COSV55245067; called by muse, mutect2, varscan2
- OPTN | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53810468; called by muse, mutect2, varscan2
- OR10AG1 | c.493A>T p.I165F | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56632420; called by muse, mutect2, varscan2
- OR10G7 | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 41/292 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV57866676; called by muse, mutect2, varscan2
- OR10J1 | c.752A>G p.Y251C | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV71128640; called by muse, mutect2, varscan2
- OR10Q1 | c.696C>A p.S232R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369464101, COSV57470171; called by mutect2, varscan2
- OR11L1 | c.541C>T p.L181F | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.842); catalogued as rs1185063378, COSV63314096, COSV63315574; called by muse, mutect2, varscan2
- OR14A16 | c.675G>T p.K225N | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV62926354, COSV62926964; called by muse, mutect2, varscan2
- OR1F1 | c.493C>G p.P165A | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV58960778; called by muse, mutect2
- OR2AG2 | c.951G>C p.*317Yext*? | Nonstop Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as COSV58454949; called by muse, mutect2
- OR2M4 | c.359A>T p.Y120F | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60707901; called by muse, mutect2
- OR2T34 | c.598T>A p.Y200N | Missense Mutation (SNP) | VAF 46/497 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60900155; called by muse, mutect2
- OR4B1 | c.198G>T p.L66F | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.721); catalogued as COSV58882543; called by muse, mutect2, varscan2
- OR4D2 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.864); catalogued as rs1458246151, COSV73459742; called by muse, mutect2, varscan2
- OR4N2 | c.115C>A p.L39I | Missense Mutation (SNP) | VAF 83/483 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV60050213, COSV60051859; called by muse, mutect2, varscan2
- OR4N2 | c.635T>A p.L212Q | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60050882; called by muse, mutect2, varscan2
- OR51D1 | c.712G>C p.V238L | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs755693316, COSV62914069; called by muse, mutect2, varscan2
- OR56A3 | c.664T>C p.Y222H | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61568888; called by muse, mutect2, varscan2
- OR56A4 | c.959G>A p.R320K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.026); catalogued as COSV100417614, COSV58109874; called by muse, mutect2, varscan2
- OR5B12 | c.539C>G p.P180R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as COSV56904652; called by muse, mutect2, varscan2
- OR5D13 | c.192C>A p.F64L | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV100686783, COSV62333353; called by mutect2, varscan2
- OR5D13 | c.193C>A p.L65I | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100686784; called by muse, mutect2, varscan2
- OR5D14 | c.473C>A p.P158H | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV100162591, COSV59455986; called by muse, mutect2, varscan2
- OR5F1 | c.531C>A p.F177L | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV53545459, COSV53546047; called by muse, mutect2, varscan2
- OR5H15 | c.697G>T p.G233C | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV62947746; called by muse, mutect2, varscan2
- OR5L1 | c.79C>A p.L27I | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as COSV61733512; called by muse, mutect2, varscan2
- OR5T3 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as rs1355765846, COSV100282731; called by muse, mutect2, varscan2
- OR6C76 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.37); catalogued as rs1194295932, COSV100093969; called by muse, mutect2
- OR6K2 | c.206T>A p.L69Q | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62743348; called by muse, mutect2, varscan2
- OR7D4 | c.160C>A p.H54N | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV100432641; called by muse, mutect2, varscan2
- OR8G1 | c.307T>A p.F103I | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as COSV100422300; called by muse, varscan2
- OR8G1 | c.367T>A p.Y123N | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100422301; called by muse, varscan2
- OR8J1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0.006); catalogued as COSV57317688; called by muse, mutect2, varscan2
- OR8K3 | c.463A>T p.I155F | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV57131197; called by muse, mutect2, varscan2
- OR8U1 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs747208338, COSV100163817; called by muse, mutect2, varscan2
- OR9Q1 | c.335G>A p.C112Y | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs190932713, COSV59038788; called by muse, mutect2, varscan2
- OSBPL3 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as COSV57655285; called by muse, mutect2
- OSBPL6 | c.1153+1G>T p.X385_splice | Splice Site (SNP) | VAF 19/82 reads (23%) | catalogued as COSV51915234; called by muse, mutect2, varscan2
- OTOF | c.5002C>A p.L1668M (on ENST00000272371 / NM_194248.3; = p.L901M on NM_004802.4) | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV55500752; called by muse, mutect2, varscan2
- P2RX1 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs756570639, COSV56653510; called by muse, mutect2, varscan2
- PAH | c.968C>A p.T323K | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM1314656, COSV61015544, COSV61016299; called by muse, mutect2
- PAK3 | c.1555G>A p.V519M (on ENST00000262836 / NM_001324328.2; = p.V504M on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99456832; called by muse, mutect2, varscan2
- PAPPA | c.3091C>A p.H1031N | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs764881805, COSV100073324; called by muse, mutect2, varscan2
- PAPSS2 | c.487C>A p.L163I | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV63263102; called by muse, mutect2, varscan2
- PCDH10 | c.2592G>C p.Q864H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.556); catalogued as COSV52091717; called by mutect2, varscan2
- PCDH11X | c.3029G>T p.R1010I | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs752617822, COSV53457117; called by muse, mutect2, varscan2
- PCDH15 | c.4771C>G p.L1591V | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.955); catalogued as COSV64687149; called by muse, mutect2
- PCDH15 | c.5050A>C p.K1684Q | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV57291795; called by muse, mutect2, varscan2
- PCDHA13 | c.775A>C p.T259P | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56493070; called by muse, mutect2, varscan2
- PCDHA4 | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.323); catalogued as COSV63540466; called by muse, mutect2, varscan2
- PCDHA6 | c.1890G>T p.E630D | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV65343454; called by muse, mutect2, varscan2
- PCDHB16 | c.1921G>T p.V641L | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53360912; called by muse, mutect2, varscan2
- PCDHB5 | c.518G>T p.S173I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV50649543; called by muse, mutect2, varscan2
- PCDHB5 | c.968G>C p.G323A | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.9); catalogued as COSV50649574; called by muse, mutect2, varscan2
- PCDHGA3 | c.124G>T p.G42C | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53928931; called by muse, mutect2, varscan2
- PCLO | c.2119G>C p.V707L | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV61627795; called by muse, mutect2, varscan2
- PDCD10 | c.225C>G p.N75K | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); catalogued as COSV101208518, COSV67102989; called by muse, mutect2, varscan2
- PDE1C | c.758T>A p.L253Q | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58510416; called by muse, mutect2
- PDS5A | c.2233G>T p.A745S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as COSV57824736; called by muse, varscan2
- PEX2 | c.445G>T p.G149C | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as COSV100824735; called by muse, mutect2, varscan2
- PGM5 | c.1404C>A p.S468R | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.365); catalogued as COSV67167337; called by muse, mutect2, varscan2
- PHF14 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as COSV68854967, COSV68856132; called by muse, mutect2, varscan2
- PHOSPHO2 | c.643C>G p.L215V | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as COSV99775631; called by muse, mutect2
- PICK1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.651); catalogued as rs200906170, COSV63660060; called by muse, mutect2, varscan2
- PIK3CA | c.1024A>T p.T342S | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.554); catalogued as COSV55910268, COSV99846471; called by muse, mutect2, varscan2
- PIK3CB | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV56685055; called by muse, mutect2, varscan2
- PIWIL1 | c.636T>A p.Y212* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as COSV55345793; called by muse, mutect2, varscan2
- PKD2L2 | c.1674G>C p.E558D | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.058); catalogued as COSV50365535; called by muse, mutect2, varscan2
- PKHD1L1 | c.12433C>A p.P4145T | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.021); catalogued as COSV65741146; called by muse, mutect2, varscan2
- PLA2G12B | c.74C>A p.P25H | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV100887991; called by muse, mutect2, varscan2
- PLA2G7 | c.509A>G p.H170R | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.019); catalogued as rs1397838503, COSV51259673; called by muse, mutect2
- PLEKHA7 | c.2096G>T p.C699F | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV63045195; called by mutect2, varscan2
- PLXDC2 | c.156G>T p.E52D | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV65914681; called by muse, varscan2
- PLXDC2 | c.171T>A p.D57E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.036); catalogued as COSV65914685; called by muse, varscan2
- PMS1 | c.425C>G p.T142S | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); catalogued as COSV59714833, COSV59715835; called by muse, mutect2
- POF1B | c.1066A>T p.K356* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV53132842; called by muse, mutect2
- POP1 | c.2544C>G p.I848M | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV62892445; called by muse, mutect2, varscan2
- PPARGC1A | c.1379C>A p.A460D | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99337581; called by mutect2, varscan2
- PPM1D | c.901C>A p.L301I | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.309); catalogued as COSV59955220; called by muse, varscan2
- PRDM9 | c.769G>A p.G257R | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770993453, COSV57005100; called by muse, mutect2, varscan2
- PREPL | c.365A>T p.Y122F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53216165; called by muse, mutect2, varscan2
- PRH1 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.958); catalogued as COSV70371852; called by muse, mutect2, varscan2
- PRMT3 | c.1347G>T p.T449= | Splice Region (SNP) | VAF 23/92 reads (25%) | catalogued as COSV58176188; called by muse, mutect2, varscan2
- PRSS48 | c.485G>C p.R162T | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV101490163; called by muse, mutect2, varscan2
- PRUNE2 | c.8722C>A p.H2908N | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56315764; called by muse, mutect2, varscan2
- PRUNE2 | c.6178G>T p.G2060C | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV65040437; called by muse, mutect2, varscan2
- PTBP2 | c.188G>C p.G63A (on ENST00000426398 / NM_001300986.2; = p.G55A on NM_021190.4) | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV64624120; called by muse, mutect2, varscan2
- PTDSS1 | c.523G>T p.G175C | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61264342; called by muse, mutect2, varscan2
- PTPRB | c.3674C>A p.T1225K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.094); catalogued as COSV54238449, COSV99717361; called by muse, mutect2, varscan2
- PTPRD | c.2237G>T p.G746V | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV61932326, COSV61938434; called by muse, mutect2, varscan2
- PTPRZ1 | c.3568G>A p.D1190N | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.156); catalogued as rs1169076011, COSV66434742; called by muse, mutect2
- PTPRZ1 | c.6653C>A p.P2218H | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66434748; called by muse, mutect2, varscan2
- PURA | c.744G>T p.E248D | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100495700; called by muse, mutect2, varscan2
- R3HDM1 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51523140; called by muse, mutect2, varscan2
- RADIL | c.3120G>T p.L1040= | Splice Region (SNP) | VAF 3/16 reads (19%) | catalogued as COSV68200244; called by muse, mutect2
- RASIP1 | c.2381G>A p.R794Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.12); catalogued as COSV99710606; called by muse, mutect2, varscan2
- RBM47 | c.1000G>T p.G334C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.713); catalogued as COSV55933453, COSV99921716; called by mutect2, varscan2
- RCSD1 | c.274A>T p.N92Y | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63258588; called by muse, mutect2
- RECQL5 | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.115); catalogued as COSV58639161; called by muse, mutect2
- REM1 | c.461dup p.S155Qfs*16 | Frame Shift Ins (INS) | VAF 8/57 reads (14%) | catalogued as rs781374050; called by mutect2*, pindel, varscan2*
- REV1 | c.2989C>G p.Q997E | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV51483965; called by muse, mutect2
- RFX4 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV63504073; called by muse, mutect2, varscan2
- RGS1 | c.377C>A p.S126Y | Missense Mutation (SNP) | VAF 60/196 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV66505102; called by muse, mutect2, varscan2
- RGS3 | c.685T>G p.S229A (on ENST00000350696 / NM_001282923.2; = p.S117A on NM_017790.4) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV58280107; called by mutect2, varscan2
- RGS7 | c.572G>A p.S191N | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58536945; called by muse, mutect2, varscan2
- RHBDF2 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as rs778354186, COSV51684253; called by muse, mutect2, varscan2
- RHBDF2 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs769387875, COSV57420705; called by mutect2, varscan2
- RIMS2 | c.2836G>A p.G946R (on ENST00000666250 / NM_001348490.2; = p.G754R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.981); catalogued as rs1463677242, COSV51671431; called by muse, mutect2, varscan2
- RNF150 | c.1288G>T p.D430Y | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV60789438; called by muse, mutect2, varscan2
- ROBO4 | c.1505-2A>G p.X502_splice | Splice Site (SNP) | VAF 12/63 reads (19%) | catalogued as COSV60623012; called by muse, mutect2, varscan2
- RP1 | c.13C>G p.P5A | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as COSV55114526, COSV99609488; called by muse, mutect2, varscan2
- RP1L1 | c.5408C>A p.T1803N | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV66754042; called by muse, mutect2, varscan2
- RPH3A | c.668C>A p.A223D (on ENST00000389385 / NM_001143854.2; = p.A219D on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV66990621; called by muse, mutect2, varscan2
- RPTN | c.179T>C p.L60P | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV60166945; called by muse, mutect2, varscan2
- RTL3 | c.940G>C p.D314H | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV58183814; called by muse, mutect2, varscan2
- RTN1 | c.1544G>A p.G515D | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV50721410; called by muse, mutect2, varscan2
- RTP2 | c.148C>A p.Q50K | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as COSV64078890, COSV64078927; called by muse, mutect2, varscan2
- RYR2 | c.6649C>A p.H2217N | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM0910990, COSV63678452; called by muse, mutect2, varscan2
- RYR2 | c.10558G>T p.E3520* | Nonsense Mutation (SNP) | VAF 62/254 reads (24%) | catalogued as COSV63666600, COSV63678462; called by muse, mutect2, varscan2
- RYR2 | c.12853T>G p.S4285A | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.366); catalogued as COSV63678474; called by muse, mutect2
- SAGE1 | c.1277C>G p.P426R | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV61012617; called by muse, mutect2, varscan2
- SALL1 | c.218T>A p.I73N | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51756063; called by muse, mutect2, varscan2
- SAMD9 | c.3237C>A p.N1079K | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV66074413; called by muse, mutect2, varscan2
- SBF1 | c.287C>G p.T96R | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.025); catalogued as rs1449459235, COSV62367078; called by muse, mutect2, varscan2
- SBF2 | c.3616G>T p.V1206F | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56296658; called by muse, mutect2, varscan2
- SCAI | c.145G>A p.D49N (on ENST00000336505 / NM_001144877.3; = p.D72N on NM_173690.5) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.681); catalogued as COSV60611888; called by muse, mutect2, varscan2
- SCD5 | c.84G>T p.E28D | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1215210110, COSV51102360, COSV51104217; called by muse, mutect2, varscan2
- SCN8A | c.4170G>C p.K1390N | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.479); catalogued as COSV61979622, COSV61985254; called by muse, mutect2
- SDK1 | c.6269G>T p.S2090I | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV67364220; called by muse, mutect2, varscan2
- SEMA3D | c.69G>A p.M23I | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52391376; called by muse, mutect2, varscan2
- SEMA6D | c.1909G>C p.D637H | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.364); catalogued as rs1228524674, COSV60375622; called by muse, mutect2, varscan2
- SEPTIN11 | c.28-1G>A p.X10_splice | Splice Site (SNP) | VAF 10/71 reads (14%) | catalogued as COSV53581585, COSV53583202; called by muse, mutect2, varscan2
- SERPINB12 | c.617C>G p.T206R | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54032695; called by muse, mutect2, varscan2
- SERPINB2 | c.48C>G p.F16L | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as COSV55091920; called by muse, mutect2
- SERPINB7 | c.310G>C p.A104P | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs761391967, COSV60533380, COSV60535037; called by muse, mutect2, varscan2
- SERPINH1 | c.571G>C p.D191H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as COSV100825038; called by muse, mutect2
- SETBP1 | c.3285C>A p.F1095L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99952502; called by muse, mutect2, varscan2
- SETBP1 | c.3286C>A p.H1096N | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99952505; called by muse, mutect2, varscan2
- SF3B4 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV54964998; called by muse, mutect2
- SHPRH | c.2780C>T p.S927F | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51607785; called by muse, mutect2, varscan2
- SI | c.2819G>T p.R940I | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV52273763; called by muse, mutect2, varscan2
- SI | c.2693C>A p.P898Q | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV52273792; called by muse, mutect2, varscan2
- SIGLEC12 | c.429G>C p.A143= (on ENST00000291707 / NM_053003.4; = p.A25= on NM_033329.2) | Splice Region (SNP) | VAF 13/54 reads (24%) | catalogued as rs200855532, COSV52460840; called by muse, mutect2, varscan2
- SIGLEC15 | c.713_714insA p.A239Gfs*73 | Frame Shift Ins (INS) | VAF 5/23 reads (22%) | catalogued as COSV101248774; called by mutect2, pindel, varscan2
- SIM1 | c.1234A>C p.T412P | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV53490895; called by muse, mutect2, varscan2
- SIRT7 | c.790A>T p.I264F | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58711081; called by muse, mutect2, varscan2
- SLC12A1 | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0.15); catalogued as COSV66793794; called by muse, mutect2, varscan2
- SLC12A3 | c.2086C>A p.H696N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.306); catalogued as COSV52634087; called by muse, mutect2, varscan2
- SLC17A3 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775251332, COSV100399122; called by muse, mutect2, varscan2
- SLC25A37 | c.704A>T p.Q235L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV51563720; called by muse, mutect2, varscan2
- SLC25A38 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56194194; called by muse, mutect2, varscan2
- SLC27A4 | c.49G>T p.V17L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV55959578; called by muse, mutect2, varscan2
- SLC2A12 | c.721A>G p.R241G | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV99259768; called by muse, mutect2, varscan2
- SLC37A3 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58264250; called by muse, mutect2, varscan2
- SLC39A14 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 26/137 reads (19%) | catalogued as COSV51483636; called by muse, mutect2, varscan2
- SLC8A1 | c.2902T>A p.C968S | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV60476924; called by muse, mutect2
- SLCO1C1 | c.1259G>T p.S420I | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs748531484, COSV56871110, COSV99859449; called by muse, mutect2, varscan2
- SLCO5A1 | c.841A>G p.I281V | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as rs201092499; called by muse, mutect2, varscan2
- SLFN11 | c.224T>A p.L75Q | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.084); catalogued as COSV57698377; called by muse, mutect2, varscan2
- SLIT2 | c.4281G>T p.R1427S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.11); catalogued as COSV56568303; called by muse, mutect2, varscan2
- SLITRK1 | c.2017T>A p.W673R | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.25); catalogued as COSV65675095; called by muse, mutect2, varscan2
- SLITRK3 | c.2667G>T p.R889S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.177); catalogued as COSV53847199; called by muse, mutect2, varscan2
- SLITRK4 | c.320G>A p.S107N | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.119); catalogued as COSV62023196; called by muse, mutect2, varscan2
- SMO | c.1640G>T p.R547L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV50826811, COSV50833643; called by muse, mutect2, varscan2
- SMOC1 | c.115C>A p.R39S | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.144); catalogued as COSV62759538, COSV62760439; called by muse, mutect2, varscan2
- SMOC1 | c.590C>A p.T197K | Missense Mutation (SNP) | VAF 14/422 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV62760446; called by muse, mutect2
- SORBS1 | c.3492G>C p.Q1164H | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.598); catalogued as COSV53356036, COSV99527944; called by muse, mutect2, varscan2
- SORCS1 | c.2341G>T p.V781L | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV53857213; called by muse, mutect2, varscan2
- SORCS1 | c.1398G>T p.M466I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV53857228; called by muse, mutect2, varscan2
- SOX9 | c.500A>C p.K167T | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV99818267; called by muse, mutect2
- SP4 | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as COSV99754217; called by muse, mutect2, varscan2
- SPAG17 | c.3128G>A p.G1043E | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60456653; called by muse, mutect2, varscan2
- SPAM1 | c.922T>A p.F308I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56142751; called by muse, mutect2, varscan2
- SPC25 | c.609G>T p.K203N | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV99960381; called by muse, mutect2
- SPEN | c.2593G>C p.E865Q | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV65360446; called by muse, mutect2, varscan2
- SPEN | c.2710G>C p.D904H | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV65360449; called by muse, mutect2, varscan2
- SPEN | c.5095C>G p.Q1699E | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.023); catalogued as rs1260835742, COSV65360451; called by muse, mutect2, varscan2
- SPHKAP | c.2850C>A p.D950E | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV60875169; called by muse, mutect2, varscan2
- SPHKAP | c.1111C>A p.H371N | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.023); catalogued as COSV60871250, COSV60892603, COSV60900352; called by muse, mutect2, varscan2
- SPOCD1 | c.2493G>T p.M831I | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV57095663; called by muse, mutect2, varscan2
- SPTA1 | c.4196T>C p.M1399T | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV100935238, COSV63751636; called by muse, mutect2, varscan2
- SPTAN1 | c.3841del p.D1281Tfs*9 | Frame Shift Del (DEL) | VAF 14/63 reads (22%) | catalogued as COSV100823346; called by mutect2, pindel, varscan2
- SRCAP | c.6711G>C p.Q2237H | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs370171603; called by muse, mutect2, varscan2
- SRRM3 | c.809G>T p.S270I | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58386669; called by muse, mutect2, varscan2
- SRSF5 | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 42/256 reads (16%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV53682213; called by muse, mutect2, varscan2
- SSH2 | c.479T>A p.V160E | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52170404; called by muse, mutect2, varscan2
- ST6GAL2 | c.1269G>T p.E423D | Missense Mutation (SNP) | VAF 40/135 reads (30%) | PolyPhen benign (0.241); catalogued as COSV100699538, COSV62416365; called by muse, mutect2, varscan2
- ST8SIA6 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 20/218 reads (9%) | catalogued as COSV66467456; called by muse, mutect2
- STAM | c.67G>C p.A23P | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66325185; called by muse, mutect2
- STARD13 | c.509G>T p.G170V (on ENST00000336934 / NM_001243476.3; = p.G52V on NM_052851.3) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.133); catalogued as COSV55229423; called by muse, mutect2, varscan2
- STARD8 | c.1601C>A p.T534N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52924678; called by muse, mutect2, varscan2
- STT3A | c.1671G>T p.Q557H | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV67064553; called by muse, mutect2, varscan2
- STYXL2 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV54804042; called by muse, mutect2, varscan2
- SUCO | c.2233C>T p.P745S | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV55263980; called by muse, mutect2
- SULT6B1 | c.529+1G>T p.X177_splice (on ENST00000535679 / NM_001367551.1; = p.X139_splice on NM_001032377.2) | Splice Site (SNP) | VAF 12/108 reads (11%) | catalogued as COSV53194093; called by muse, mutect2, varscan2
- SYNPO2 | c.2557G>T p.A853S | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV61109197; called by muse, mutect2, varscan2
- SYT4 | c.1092T>A p.C364* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV54899717, COSV54901545; called by muse, mutect2, varscan2
- TAAR2 | c.629G>T p.G210V (on ENST00000367931 / NM_001033080.1; = p.G165V on NM_014626.3) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV51578404, COSV51578868; called by muse, mutect2, varscan2
- TAAR6 | c.914C>A p.A305D | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV51583274; called by muse, mutect2
- TACC1 | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs1273568867, COSV52523056; called by muse, mutect2, varscan2
- TAF1L | c.3238C>A p.R1080S | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV54260497, COSV54262664; called by muse, mutect2, varscan2
- TAGAP | c.1346C>A p.S449* | Nonsense Mutation (SNP) | VAF 13/142 reads (9%) | catalogued as COSV57851201, COSV57852090; called by muse, mutect2
- TBC1D22B | c.1129G>A p.V377M | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751755841, COSV65142640; called by muse, mutect2, varscan2
- TFAP2A | c.578C>G p.S193C (on ENST00000482890; = p.S185C on NM_001032280.3) | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as COSV60232811, COSV60236395; called by muse, mutect2, varscan2
- TFCP2L1 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV55290476; called by muse, mutect2
- TGM6 | c.524A>T p.Q175L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.225); catalogued as COSV52478991; called by muse, varscan2
- TGM6 | c.1987C>T p.Q663* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | catalogued as COSV99171723; called by muse, mutect2, varscan2
- TIGD7 | c.519G>C p.Q173H | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1261010183, COSV99239779; called by muse, mutect2
- TIGD7 | c.11G>C p.R4T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.324); catalogued as rs936587674, COSV99239780; called by muse, mutect2
- TLN2 | c.6694G>T p.E2232* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | catalogued as COSV60888583, COSV60894788; called by muse, mutect2, varscan2
- TLR4 | c.94-1G>T p.X32_splice | Splice Site (SNP) | VAF 22/61 reads (36%) | catalogued as COSV100790624, COSV99053085; called by muse, mutect2, varscan2
- TMCC3 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.912); catalogued as COSV54153638, COSV99705648; called by muse, mutect2, varscan2
- TMEM116 | c.324C>G p.I108M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV61391603; called by muse, mutect2, varscan2
- TMEM200A | c.1250C>A p.P417Q | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as COSV51651743; called by muse, varscan2
- TMPRSS11E | c.171G>C p.L57F | Missense Mutation (SNP) | VAF 76/310 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV59518682; called by muse, mutect2, varscan2
- TMPRSS11E | c.775G>T p.G259C | Missense Mutation (SNP) | VAF 78/308 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV59518693; called by muse, mutect2, varscan2
- TMTC3 | c.1285G>C p.E429Q | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.652); catalogued as COSV57123451; called by muse, mutect2, varscan2
- TNFSF18 | c.283T>A p.S95T | Missense Mutation (SNP) | VAF 51/192 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs750915789, COSV99513887; called by muse, mutect2, varscan2
- TNN | c.326T>A p.L109Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53424556; called by muse, mutect2, varscan2
- TNPO2 | c.728T>A p.V243E | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV63508028; called by muse, mutect2, varscan2
- TNS3 | c.2074A>T p.T692S | Missense Mutation (SNP) | VAF 49/366 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); catalogued as COSV60789604; called by muse, mutect2, varscan2
- TPI1 | c.447G>T p.Q149H (on ENST00000229270; = p.Q112H on NM_000365.6) | Missense Mutation (SNP) | VAF 51/515 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV51290105; called by muse, mutect2
- TRAF3IP3 | c.101G>C p.R34P | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50552013; called by muse, mutect2, varscan2
- TRAM2 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as COSV51732336, COSV51735114; called by muse, mutect2, varscan2
- TREML2 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.381); catalogued as COSV72439084; called by muse, mutect2
- TRIM42 | c.1017C>A p.S339R | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.675); catalogued as rs779021255, COSV53881739, COSV53885497; called by muse, mutect2, varscan2
- TRIM58 | c.763C>A p.L255M | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV100824962; called by muse, mutect2, varscan2
- TRPC7 | c.341T>C p.I114T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61456698; called by muse, mutect2, varscan2
- TRPS1 | c.2519G>T p.R840L (on ENST00000220888 / NM_001330599.2; = p.R853L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.687); catalogued as COSV55235285, COSV55249792; called by muse, mutect2, varscan2
- TRPV3 | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.948); catalogued as COSV56790482; called by muse, mutect2, varscan2
- TRPV5 | c.1265G>T p.G422V | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54684716, COSV54686070; called by muse, mutect2, varscan2
- TRRAP | c.10048G>T p.V3350L (on ENST00000359863 / NM_001244580.1; = p.V3321L on NM_003496.3) | Missense Mutation (SNP) | VAF 46/277 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV62840971, COSV62842596; called by muse, mutect2, varscan2
- TSPAN2 | c.294A>G p.I98M | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65689857; called by muse, mutect2, varscan2
- TTC39B | c.1754G>A p.C585Y | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1173300607, COSV52609298; called by muse, mutect2, varscan2
- TTF1 | c.916G>C p.D306H | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.03); catalogued as COSV57503421; called by muse, mutect2
- TTK | c.2411G>C p.G804A | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.08); catalogued as COSV57883192; called by muse, mutect2, varscan2
- TTN | c.66399G>T p.W22133C (on ENST00000591111; = p.W14709C on NM_003319.4) | Missense Mutation (SNP) | VAF 5/61 reads (8%) | PolyPhen probably damaging (0.999); catalogued as COSV59988204; called by muse, mutect2
- TTN | c.61174G>T p.E20392* (on ENST00000591111; = p.E12968* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV59988231; called by muse, mutect2, varscan2
- TTN | c.59488C>A p.L19830I (on ENST00000591111; = p.L12406I on NM_003319.4) | Missense Mutation (SNP) | VAF 16/216 reads (7%) | PolyPhen benign (0.047); catalogued as COSV59988281; called by muse, mutect2
- TTN | c.56715G>C p.K18905N (on ENST00000591111; = p.K11481N on NM_003319.4) | Missense Mutation (SNP) | VAF 9/133 reads (7%) | PolyPhen probably damaging (0.997); catalogued as COSV59988315; called by muse, mutect2
- TTN | c.48197C>A p.T16066N (on ENST00000591111; = p.T8642N on NM_003319.4) | Missense Mutation (SNP) | VAF 165/664 reads (25%) | PolyPhen benign (0.295); catalogued as COSV59988403; called by muse, mutect2, varscan2
- TTN | c.31310G>A p.R10437K (on ENST00000591111; = p.R9510K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/234 reads (8%) | PolyPhen possibly damaging (0.87); catalogued as COSV59988431; called by muse, mutect2
- TTN | c.26299T>A p.S8767T (on ENST00000591111; = p.S7840T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/86 reads (24%) | PolyPhen benign (0); catalogued as rs761372985, COSV59988455; called by muse, mutect2, varscan2
- TTN | c.21699A>C p.K7233N (on ENST00000591111; = p.K6306N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/343 reads (9%) | PolyPhen probably damaging (0.982); catalogued as COSV59988470, COSV60115039; called by muse, mutect2
- TTN | c.21443T>A p.L7148Q (on ENST00000591111; = p.L6221Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/70 reads (9%) | PolyPhen benign (0.284); catalogued as COSV59988484; called by muse, mutect2
- TTN | c.20370T>A p.D6790E (on ENST00000591111; = p.D5863E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/125 reads (21%) | PolyPhen benign (0.006); catalogued as COSV59988495; called by muse, mutect2, varscan2
- TTN | c.6716C>G p.S2239C (on ENST00000591111; = p.S2193C on NM_003319.4) | Missense Mutation (SNP) | VAF 10/71 reads (14%) | PolyPhen benign (0.298); catalogued as COSV59988515; called by mutect2, varscan2
- TTN | c.2506G>C p.G836R (on ENST00000591111; = p.G790R on NM_003319.4) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | PolyPhen probably damaging (0.996); catalogued as COSV59988553, COSV60007599; called by muse, mutect2, varscan2
- TXLNG | c.882C>G p.F294L | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as COSV101200560; called by muse, mutect2, varscan2
- TYR | c.1477G>T p.A493S | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs146020203; called by muse, mutect2, varscan2
- U2SURP | c.2371G>C p.E791Q | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV67530545; called by muse, mutect2, varscan2
- UBE2W | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100708727; called by muse, mutect2, varscan2
- UBR1 | c.4739A>T p.Q1580L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV51928158, COSV99316838; called by muse, mutect2, varscan2
- UBXN1 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs1234093712, COSV53656883; called by muse, mutect2, varscan2
- UGT2B4 | c.832G>T p.G278* | Nonsense Mutation (SNP) | VAF 30/228 reads (13%) | catalogued as COSV100522291; called by muse, mutect2, varscan2
- UNC5A | c.1283C>A p.T428N | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.091); catalogued as rs150952594, COSV56167042; called by muse, mutect2, varscan2
- UNC79 | c.2388G>A p.M796I (on ENST00000393151 / NM_001346218.2; = p.M619I on NM_020818.5) | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.636); catalogued as rs1267848033, COSV56382650; called by muse, mutect2
- UNC79 | c.4324G>C p.A1442P (on ENST00000393151 / NM_001346218.2; = p.A1265P on NM_020818.5) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.411); catalogued as COSV56372746, COSV56382665, COSV99829498; called by muse, mutect2, varscan2
- USH2A | c.8644G>T p.G2882* | Nonsense Mutation (SNP) | VAF 64/254 reads (25%) | catalogued as COSV100231608; called by muse, mutect2, varscan2
- USH2A | c.3097G>T p.D1033Y | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56355999; called by muse, mutect2, varscan2
- USH2A | c.2294A>T p.Q765L | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56356056; called by muse, varscan2
- USO1 | c.2498G>T p.G833V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV53706196; called by muse, mutect2, varscan2
- USP13 | c.1177G>T p.G393C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99830880; called by muse, mutect2, varscan2
- USP13 | c.1178G>T p.G393V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55863521, COSV99830882; called by muse, mutect2, varscan2
- UTP25 | c.1139G>T p.S380I | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.823); catalogued as COSV71965870; called by muse, mutect2, varscan2
- UTP6 | c.543+1G>T p.X181_splice | Splice Site (SNP) | VAF 16/122 reads (13%) | catalogued as COSV55572610; called by muse, mutect2, varscan2
- VCAN | c.7845C>A p.D2615E | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54102745, COSV54108321; called by muse, mutect2, varscan2
- VWA7 | c.2094C>G p.F698L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV65172991; called by muse, mutect2
- WDR33 | c.935G>T p.C312F | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59247906; called by muse, mutect2, varscan2
- WDR49 | c.1462G>T p.G488C (on ENST00000308378 / NM_001366158.1; = p.G829C on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs962885702, COSV57706292, COSV57706874; called by muse, mutect2, varscan2
- WDR49 | c.842A>T p.Q281L (on ENST00000308378 / NM_001366158.1; = p.Q622L on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV57706301; called by muse, mutect2, varscan2
- WSCD2 | c.1304G>T p.G435V | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV54581160, COSV54583370; called by muse, mutect2, varscan2
- XIRP2 | c.773T>A p.V258D (on ENST00000628543; = p.V433D on NM_152381.6) | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as COSV54693549; called by muse, mutect2, varscan2
- XIRP2 | c.1173G>A p.W391* (on ENST00000628543; = p.W566* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV54693559, COSV99740085; called by muse, mutect2, varscan2
- YTHDF2 | c.587G>T p.S196I | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.194); catalogued as COSV65723070; called by muse, mutect2, varscan2
- ZC3H6 | c.2461G>T p.G821C | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.628); catalogued as COSV59667095; called by muse, mutect2, varscan2
- ZDBF2 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.158); catalogued as COSV65623350, COSV65624263; called by muse, mutect2, varscan2
- ZFHX3 | c.5770G>C p.G1924R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV51710890, COSV51715049; called by muse, mutect2, varscan2
- ZFYVE9 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.989); catalogued as COSV55092753; called by muse, mutect2, varscan2
- ZHX1 | c.2258G>T p.R753I | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.407); catalogued as COSV52876174; called by muse, mutect2, varscan2
- ZNF107 | c.1913G>T p.C638F | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61328012; called by muse, mutect2, varscan2
- ZNF208 | c.3758A>G p.Y1253C | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs889097700, COSV68103633; called by muse, mutect2, varscan2
- ZNF287 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.197); catalogued as COSV67688330; called by muse, mutect2, varscan2
- ZNF343 | c.841A>G p.R281G | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1411464675, COSV53853419; called by muse, mutect2, varscan2
- ZNF385D | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757067821, COSV55751804; called by muse, mutect2, varscan2
- ZNF385D | c.446C>A p.T149N | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.363); catalogued as rs1405683003, COSV55751815, COSV99873201; called by muse, mutect2, varscan2
- ZNF423 | c.1844C>A p.S615* (on ENST00000563137 / NM_001379286.1; = p.S607* on NM_015069.4) | Nonsense Mutation (SNP) | VAF 21/69 reads (30%) | catalogued as rs754474774, COSV52184613, COSV52199472; called by muse, mutect2, varscan2
- ZNF440 | c.1367G>A p.R456K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV58371249; called by muse, mutect2, varscan2
- ZNF440 | c.1507G>C p.D503H | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.429); catalogued as COSV100407442; called by muse, mutect2
- ZNF675 | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as COSV63095707; called by muse, mutect2, varscan2
- ZNF768 | c.237T>G p.F79L | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV53223581; called by muse, mutect2, varscan2
- ZNF777 | c.1822G>A p.G608R | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.313); catalogued as rs764277448, COSV56097092; called by muse, mutect2, varscan2
- ZNF780B | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55463408; called by muse, mutect2, varscan2
- ZNF804B | c.2885C>T p.P962L | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV60821701, COSV60826402; called by muse, mutect2, varscan2
- ZNF816-ZNF321P | c.511C>G p.Q171E | Missense Mutation (SNP) | VAF 23/248 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.356); catalogued as COSV100008374, COSV100008424; called by muse, mutect2
- ZNRF3 | c.1054A>G p.S352G (on ENST00000544604 / NM_001206998.2; = p.S252G on NM_032173.3) | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV60433110; called by muse, mutect2, varscan2
- ZP3 | c.192G>T p.K64N (on ENST00000394857 / NM_001110354.2; = p.K13N on NM_007155.6) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV100334489; called by muse, mutect2, varscan2
- ZUP1 | c.1226G>T p.G409V | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63944244; called by muse, mutect2, varscan2
- ABCA13 | c.589del p.D197Mfs*7 | Frame Shift Del (DEL) | VAF 22/104 reads (21%) | called by mutect2, pindel, varscan2
- APOBR | c.2493_2518del p.V832Rfs*52 (on ENST00000431282; = p.V841Rfs*52 on NM_018690.4) | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | called by mutect2, pindel
- ARHGEF35 | c.658G>C p.G220R | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- ATF7IP | c.2107dup p.R703Kfs*32 | Frame Shift Ins (INS) | VAF 23/56 reads (41%) | called by mutect2, pindel, varscan2
- CDKN1B | c.88_94del p.R30Sfs*10 | Frame Shift Del (DEL) | VAF 21/125 reads (17%) | called by mutect2, pindel, varscan2
- CDKN2A | c.300_319del p.G101Rfs*12 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel
- COL5A3 | c.4358dup p.G1454Rfs*103 | Frame Shift Ins (INS) | VAF 23/80 reads (29%) | called by mutect2, pindel, varscan2
- E2F2 | c.1134del p.H379Tfs*22 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- GDF10 | c.1374G>C p.E458D | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- GGNBP2 | c.1258A>T p.S420C | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- ITK | c.1290del p.I431Sfs*73 | Frame Shift Del (DEL) | VAF 17/95 reads (18%) | called by mutect2, pindel, varscan2
- MRC1 | c.4055G>T p.G1352V | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBPF26 | c.2588-1G>T p.X863_splice (on ENST00000620612; = p.X601_splice on NM_001351372.1) | Splice Site (SNP) | VAF 20/370 reads (5%) | called by muse, mutect2
- NBPF26 | c.2588G>T p.R863I (on ENST00000620612; = p.R601I on NM_001351372.1) | Missense Mutation (SNP) | VAF 19/371 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2
- NPLOC4 | c.1042del p.Q348Rfs*82 | Frame Shift Del (DEL) | VAF 19/117 reads (16%) | called by mutect2, pindel, varscan2
- NUMA1 | c.3131_3132del p.E1044Vfs*52 | Frame Shift Del (DEL) | VAF 12/90 reads (13%) | called by mutect2, pindel, varscan2
- OTOA | c.2240del p.G747Dfs*21 (on ENST00000286149; = p.G733Dfs*21 on NM_144672.4) | Frame Shift Del (DEL) | VAF 5/13 reads (38%) | called by mutect2, varscan2
- PCDHGA4 | c.2368del p.L790Sfs*10 | Frame Shift Del (DEL) | VAF 22/101 reads (22%) | called by mutect2, pindel, varscan2
- PPM1D | c.848del p.F283Sfs*37 | Frame Shift Del (DEL) | VAF 15/87 reads (17%) | called by pindel, varscan2
- RHOJ | c.109del p.L37Cfs*2 | Frame Shift Del (DEL) | VAF 18/93 reads (19%) | called by mutect2, pindel, varscan2
- SEMA5A | c.942dup p.A315Cfs*70 | Frame Shift Ins (INS) | VAF 28/104 reads (27%) | called by mutect2, pindel, varscan2
- SPTBN5 | c.156_167del p.H52_M55del | In Frame Del (DEL) | VAF 11/59 reads (19%) | called by mutect2, pindel
- SUPT20HL2 | c.1906C>G p.L636V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX15 | c.4722del p.H1574Qfs*18 (on ENST00000256246; = p.H1957Qfs*18 on NM_001350162.2) | Frame Shift Del (DEL) | VAF 26/140 reads (19%) | called by mutect2, pindel, varscan2
- TMEM51 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TYRO3 | c.768G>T p.Q256H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UBOX5 | c.1344_1363del p.L449Afs*60 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | called by mutect2, pindel
- USP6 | c.2129del p.P710Hfs*10 | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | called by mutect2, pindel, varscan2
- ZAN | c.247A>T p.N83Y | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2
- ZMIZ2 | c.1803del p.I602Sfs*60 | Frame Shift Del (DEL) | VAF 28/151 reads (19%) | called by mutect2, pindel, varscan2
- ZNHIT3 | c.20G>T p.S7I | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- ACTN2 | c.1872C>G p.S624= | Silent (SNP) | VAF 14/127 reads (11%) | catalogued as COSV63974107; called by muse, mutect2, varscan2
- ADAMTS1 | c.1560G>T p.V520= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV53169732; called by muse, mutect2, varscan2
- ADGRB3 | c.3325C>T p.L1109= | Silent (SNP) | VAF 25/272 reads (9%) | catalogued as COSV53240833, COSV99484373; called by muse, mutect2
- ADGRD1 | c.2445C>G p.A815= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV55442881; called by muse, mutect2, varscan2
- ADGRF4 | c.1185G>T p.S395= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV51949890, COSV51951513; called by muse, mutect2, varscan2
- ADGRL2 | c.3588A>T p.V1196= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV99587751; called by muse, mutect2
- ADGRL3 | c.1011G>A p.E337= (on ENST00000506720 / NM_001322402.2; = p.E269= on NM_015236.6) | Silent (SNP) | VAF 32/58 reads (55%) | catalogued as COSV72267913, COSV72269123; called by muse, mutect2, varscan2
- ANKS4B | c.936T>C p.D312= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV61139052; called by muse, mutect2, varscan2
- AP5S1 | c.147C>T p.L49= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV55693819; called by muse, mutect2
- AREL1 | c.426G>A p.V142= | Silent (SNP) | VAF 55/179 reads (31%) | catalogued as COSV62666090; called by muse, mutect2, varscan2
- ARMC9 | c.837G>T p.R279= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV63020341; called by mutect2, varscan2
- ATRNL1 | c.2247A>G p.G749= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV61802237; called by muse, mutect2, varscan2
- AXDND1 | c.576T>C p.Y192= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as rs1338672834, COSV62641557; called by muse, mutect2, varscan2
- BAALC | c.537C>A p.V179= (on ENST00000297574 / NM_001364874.1; = p.V144= on NM_024812.3) | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV52561466; called by muse, mutect2, varscan2
- BTBD7 | c.330A>G p.A110= | Silent (SNP) | VAF 25/119 reads (21%) | catalogued as COSV54135071; called by muse, mutect2, varscan2
- C16orf78 | c.447A>G p.P149= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV54555732; called by muse, mutect2, varscan2
- CACNA1D | c.717C>T p.L239= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV55443737; called by muse, varscan2
- CADPS2 | c.1032A>G p.A344= | Silent (SNP) | VAF 43/191 reads (23%) | catalogued as COSV57358652; called by muse, mutect2, varscan2
- CCDC122 | c.144G>C p.L48= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV55709183; called by muse, mutect2
- CCDC34 | c.552A>G p.R184= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100156472; called by muse, mutect2, varscan2
- CD2 | c.558C>T p.C186= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV65644083; called by muse, mutect2, varscan2
- CD7 | c.634C>A p.R212= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs768642514, COSV100444801, COSV57067938; called by muse, mutect2, varscan2
- CDH8 | c.714G>A p.E238= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as rs1039402148, COSV54857208; called by muse, mutect2, varscan2
- CES3 | c.1554C>T p.P518= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV57593209; called by muse, mutect2
- CFAP58 | c.1330C>A p.R444= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV57211816; called by muse, mutect2, varscan2
- CKAP5 | c.1731G>A p.L577= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV56366389; called by muse, mutect2, varscan2
- CLCA1 | c.1149G>T p.T383= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV52327211; called by muse, mutect2, varscan2
- COL9A1 | c.2595T>A p.P865= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV57882167; called by muse, mutect2, varscan2
- CRTAM | c.144C>A p.L48= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV99911889; called by muse, mutect2, varscan2
- CSMD3 | c.591G>T p.G197= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as COSV52152696, COSV99831117; called by muse, mutect2, varscan2
- CTPS1 | c.246C>G p.L82= | Silent (SNP) | VAF 18/194 reads (9%) | catalogued as rs1184418239, COSV65452191; called by muse, mutect2
- DCAF12L1 | c.909G>T p.L303= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV100948168, COSV64421768; called by muse, mutect2, varscan2
- DCAF4L2 | c.234G>T p.L78= | Silent (SNP) | VAF 34/133 reads (26%) | catalogued as COSV60477811; called by muse, mutect2, varscan2
- DCC | c.1254T>A p.P418= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV100498899; called by muse, mutect2, varscan2
- DCSTAMP | c.1269G>A p.K423= | Silent (SNP) | VAF 11/106 reads (10%) | catalogued as COSV52577196; called by muse, mutect2, varscan2
- DDX21 | c.1581G>T p.R527= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV62555551; called by muse, mutect2
- DGKK | c.1629C>A p.R543= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV65707069; called by muse, mutect2, varscan2
- DHPS | c.597A>G p.V199= | Silent (SNP) | VAF 54/147 reads (37%) | catalogued as rs1401865256, COSV52951955; called by muse, mutect2, varscan2
- DHX37 | c.2163C>T p.I721= | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as rs774307424, COSV58133657; called by muse, mutect2, varscan2
- DHX8 | c.258G>C p.L86= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV52252342; called by muse, mutect2, varscan2
- DNAH11 | c.8790G>T p.L2930= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV60949381; called by muse, mutect2, varscan2
- DNAH8 | c.1414C>T p.L472= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs1260619082, COSV59426341, COSV59438174; called by muse, mutect2, varscan2
- DSG4 | c.2754G>A p.V918= | Silent (SNP) | VAF 28/124 reads (23%) | catalogued as COSV57390430; called by muse, mutect2, varscan2
178 further variants in this file (0 protein-altering or splice-affecting, 156 silent, 22 other) are not listed here.
